Surgical pathology report (de-identified scan), TCGA case TCGA-LI-A9QH, project TCGA-SARC (Sarcoma), tissue source site Hartford Hospital, specimen TCGA-LI-A9QH-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

LOCATION:
SUBMITTING MD:
CC:

DIAGNOSIS

#1. SOFT TISSUE RESECTION, RIGHT CALF: UNDIFFERENTIATED PLEOMORPHIC SARCOMA (SEE COMMENT).

Tumor type (WHO):	Undifferentiated pleomorphic sarcoma (so called "MFH"); see comment
Tumor size:	18.8 cm
Tumor depth:	Deep soft tissue tumor
Histologic grade (FNCLCC):	III
Type:	3 points (pleomorphic sarcoma)
Necrosis:	1 point (<50% necrosis)
Mitoses:	3 points (24 per 10 HPF: range from 16/10HPF to 24/10HPF)
Margins:	Negative Tumor at <0.5mm from lateral and posterior margins; ~1mm proximal margin; all remaining margins more widely negative
Ancillary studies:	Negative MDM2 (on prior incisional specimen) Negative desmin, caldesmon, myogenin & S100 (this specimen)
Lymphovascular Invasion:	None observed
Lymph nodes:	None dissected
Treatment Effect:	N/A
AJCC stage:	Stage III (assuming "cM0" status)
pTNM status	pT2b, pNx (with regional neural invasion, specimen #2; see comment)

#2. RIGHT TIBIAL NERVE NODULE, EXCISION: PLEOMORPHIC SARCOMA INVOLVING SEGMENT OF PERIPHERAL NERVE (SEE COMMENT).

ICD-O-3
Sarcoma, pleomorphic cell, undifferentiated ***Electronically Signed Out***
8862/3
Code to highest 8805/3
Site: @ Caly NOS C49.2 *901127/14*

COMMENT

Although more than 90% of the tumor is undifferentiated pleomorphic sarcoma (pleomorphic "MFH") other portions of the tumor resemble low grade myxofibrosarcoma (low-grade "MFH"). Still other foci resemble pleomorphic liposarcoma with multivacuolated giant cells (suggesting the possibility of lipoblastic differentiation). S100 immunostains however are negative in these vacuolated pleomorphic giant cells (and are also negative in the spindle cell component).

With regard to the right tibial nerve nodule this constitutes regional neural/perineural invasion of the primary tumor (which does not factor into assigning primary tumor staging). This does not constitute evidence of distant metastases.

88309, 88342X4, 88305

Clinical Diagnosis and History:

Right leg sarcoma

[page 2 of 2]
Tissue(s) Submitted:

- 1: RIGHT CALF MASS
2: TIBIAL RIGHT NERVE NODULE

Gross Description:

Specimen #1 is received fresh and subsequently placed in formalin labeled right calf mass and consists of a 1,018 gram, 22.0 cm proximal to distal by 11.5 cm lateral to medial by 7.3 cm superficial to deep resection. There is a 4.7 x 1.7 cm ellipse of tan skin present on the superficial aspect of the specimen. The specimen is differentially inked proximal blue, distal green, lateral yellow, medial red, superficial orange and deep black and serially sectioned from proximal to distal. There is an 18.8 x 9.9 x 8.6 cm tan white focally necrotic mass identified which focally abuts the lateral and deep fascia coming to within less than 0.1 cm of the proximal fascia. One representative section is submitted for TCGA study Gross photographs are taken. Representative sections are submitted labeled:

- 1A-1B: mass to proximal margin
1C-1E: mass to lateral margin
1F-1K: mass to deep margin
1L: mass to superficial (orange)
1M: mass to medial
1N-1R: central sections
1S: representative skin
1T-1U: additional mass to deep margin
1V: representative distal margin (green)

Specimen #2 is received in formalin labeled tibial right nerve nodule and consists of two fragments of tan soft rubbery tissue measuring 2.6 x 0.6 x 0.3 cm and 1.6 x 0.2 x 0.1 cm, respectively, which are submitted in toto labeled 2A.

END OF REPORT

hw 1/3/14
lung
12/24/13

Source: NCI Genomic Data Commons file ab4e017e-22b8-48c3-b6bc-4fe5c95ff163 (TCGA-LI-A9QH.1CD5A8A0-EC1A-495C-8A57-912C8AC067D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).